FM case AD17114 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/9ed3ed9f-6917-49f7-adf4-0c75e1ab06fb

Male, 29.1 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the liver. Sample type: Tumor.
